TCGA case TCGA-VQ-A8PT — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5c1afb64-da74-4d2c-8be3-e6c21d2952a9

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 65.2 years (23,797 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 900 days (2.5 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 38.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 193 days; Days to treatment end: 197 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Regimen or line of therapy: XELOX; Days to treatment start: 221 days; Days to treatment end: 263 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 587 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 798 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 900 days (2.5 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A8PT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-VQ-A8PT-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VQ-A8PT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A8PT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on analyte TCGA-VQ-A8PT-01A-11R: The RNA associated with UUID 7740C28B-D60A-4304-AE33-38764FFDB984 was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-VQ-A8PT-01A-11R-A414-31: The RNA associated with UUID 2071203C-0A8D-4082-8F83-903719413E1C was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-VQ-A8PT-01A-11R-A415-13: The RNA associated with UUID BB0571D3-D4D5-4690-9B93-BB380AF6BD8E was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 900 days; disease-specific survival: no event (censored), 900 days; disease-free interval: no event (censored), 900 days; progression-free interval: no event (censored), 900 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A8PT-01A-11D-A40Z-01): tumor purity 0.78, ploidy 2.05, whole-genome doublings 0.
